Somatic mutation profile of tumor specimen TCGA-60-2696-01A (aliquot TCGA-60-2696-01A-01W-0877-08) from TCGA case TCGA-60-2696, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.6 years (27,991 days).
Specimen TCGA-60-2696-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca74b450-6ac8-41c1-b409-85e61ebb619b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2696-11A (Solid Tissue Normal), aliquot TCGA-60-2696-11A-01W-0877-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23087d1e-29bb-4635-924f-512491c0e48b

The open-access MAF lists 205 somatic variants for this specimen: 163 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 37, Frame Shift Del 8, Nonsense Mutation 7, Intron 4, Splice Site 3, Frame Shift Ins 3, In Frame Del 2, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2848C>T p.Q950* | Nonsense Mutation (SNP) | VAF 47/180 reads (26%) | catalogued as rs1060500357, CM154908, COSV62201077; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 23/109 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD5 | c.330G>T p.L110F | Missense Mutation (SNP) | VAF 108/400 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50007160; called by muse, mutect2, varscan2
- ASB17 | c.856C>A p.R286S | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.071); catalogued as rs767443611, COSV52411710; called by muse, mutect2, varscan2
- ATP23 | c.700A>G p.R234G | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1000748061; called by muse, mutect2, varscan2
- CACNG2 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV55640459; called by muse, mutect2, varscan2
- CALCR | c.1162T>C p.Y388H (on ENST00000649521 / NM_001164737.2; = p.Y372H on NM_001742.4) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1186972827; called by muse, mutect2, varscan2
- CAPN5 | c.551A>G p.N184S (on ENST00000456580; = p.N144S on NM_004055.5) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs1555040979; called by muse, mutect2, varscan2
- CDYL2 | c.606G>C p.E202D | Missense Mutation (SNP) | VAF 81/341 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.053); catalogued as COSV73647587; called by muse, mutect2, varscan2
- CSMD2 | c.8887C>T p.R2963W | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs771389828, COSV53943111; called by muse, mutect2, varscan2
- DCAF8L1 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV101491386; called by muse, mutect2, varscan2
- DCC | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181362326; called by muse, mutect2, varscan2
- DHX16 | c.1621C>G p.R541G | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100905185; called by muse, mutect2, varscan2
- DOCK2 | c.3719C>A p.A1240D | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99909644; called by muse, mutect2, varscan2
- DSTYK | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.655); catalogued as rs374400399; called by muse, mutect2, varscan2
- ELMO2 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 57/428 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs140516654, COSV51686295; called by muse, mutect2, varscan2
- EML5 | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61351269; called by muse, mutect2, varscan2
- ENPEP | c.228C>A p.D76E | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54452501; called by muse, mutect2, varscan2
- ETNPPL | c.83C>A p.S28* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as rs776914976, COSV56597022, COSV56597727, COSV56598085; called by muse, mutect2, varscan2
- FGD6 | c.3476G>T p.R1159L | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59693484; called by muse, mutect2, varscan2
- FNBP4 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as rs1000167069; called by muse, mutect2, varscan2
- FOXS1 | c.709G>C p.V237L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54067215, COSV54068151; called by mutect2, varscan2
- GGA2 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs988469550; called by muse, mutect2, varscan2
- HROB | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 134/320 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1455106287; called by muse, mutect2, varscan2
- HS6ST3 | c.1132C>G p.Q378E | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100940321, COSV65002569; called by muse, mutect2, varscan2
- IFT172 | c.4913C>T p.P1638L | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.114); catalogued as rs550224307; called by muse, mutect2
- KLB | c.1004A>G p.H335R | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs1437981506; called by muse, mutect2, varscan2
- MECOM | c.3119C>T p.A1040V (on ENST00000468789 / NM_001105078.4; = p.A1228V on NM_004991.4) | Missense Mutation (SNP) | VAF 37/496 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.837); catalogued as rs779316050; called by muse, mutect2
- MMS22L | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV51526660; called by muse, mutect2, varscan2
- MTOR | c.5239A>G p.M1747V | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV63874357; called by muse, mutect2, varscan2
- OR4C12 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 87/495 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as rs782408651; called by muse, mutect2, varscan2
- OR52M1 | c.746G>T p.C249F | Missense Mutation (SNP) | VAF 120/455 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs756589356, COSV100798609; called by muse, mutect2, varscan2
- PKHD1L1 | c.10781C>A p.A3594E | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs1488287534; called by muse, mutect2, varscan2
- PLCH1 | c.4030G>A p.V1344I (on ENST00000340059 / NM_001130960.2; = p.V1336I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1375287974; called by muse, mutect2, varscan2
- PSKH2 | c.801G>T p.Q267H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs769647020; called by muse, mutect2, varscan2
- RASA1 | c.1017+1G>C p.X339_splice | Splice Site (SNP) | VAF 54/187 reads (29%) | catalogued as CS083255; called by muse, mutect2, varscan2
- RELN | c.6034G>T p.D2012Y | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1198872899; called by muse, mutect2, varscan2
- RYR2 | c.5095C>A p.R1699S | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100773433; called by muse, mutect2, varscan2
- SKAP1 | c.358+1G>T p.X120_splice | Splice Site (SNP) | VAF 49/332 reads (15%) | catalogued as COSV100412251; called by muse, mutect2, varscan2
- SLC10A2 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs770274337; called by muse, mutect2, varscan2
- SLC30A6 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1334747139; called by muse, mutect2, varscan2
- SLCO1B3 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as rs777688375; called by muse, mutect2, varscan2
- SLIT3 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200107445, COSV99062677; called by muse, varscan2
- SMAD6 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1315294969; called by muse, mutect2, varscan2
- SYNE2 | c.8621A>G p.H2874R | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs368253284, COSV59939503; called by muse, mutect2, varscan2
- TAF6L | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367911968; called by muse, mutect2, varscan2
- TBX15 | c.637G>A p.V213M (on ENST00000369429 / NM_001330677.2; = p.V107M on NM_152380.3) | Missense Mutation (SNP) | VAF 30/818 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1365835383; called by muse, mutect2
- TBX5 | c.1473T>G p.H491Q | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.04); catalogued as COSV59863428; called by muse, mutect2, varscan2
- TIE1 | c.1640T>C p.L547S | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as rs1387238958; called by muse, mutect2, varscan2
- TNFRSF10D | c.266G>T p.R89I | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.38); catalogued as COSV57034751; called by muse, mutect2, varscan2
- TRPC7 | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 119/266 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs1041562468; called by muse, mutect2, varscan2
- TUBA3C | c.974C>A p.P325Q | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV68029607; called by muse, mutect2, varscan2
- WDR27 | c.1427A>G p.Q476R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs376495111; called by muse, varscan2
- ZNF432 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 84/426 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143578339; called by muse, mutect2, varscan2
- ZNF664 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 27/155 reads (17%) | catalogued as COSV61878106; called by muse, mutect2, varscan2
- ZNRF4 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.17); catalogued as COSV99706322; called by muse, mutect2, varscan2
- ABCC11 | c.1448G>A p.W483* | Nonsense Mutation (SNP) | VAF 63/538 reads (12%) | called by muse, mutect2, varscan2
- ABR | c.516C>G p.H172Q (on ENST00000302538 / NM_021962.5; = p.H135Q on NM_001092.5) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, mutect2
- ADGRB3 | c.2963G>T p.W988L | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGAP3 | c.788G>T p.C263F (on ENST00000622464; = p.C299F on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- AHSG | c.115_118del p.E39Qfs*6 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- AKR1B15 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- ALPK3 | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ANTXR1 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 68/375 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARHGEF28 | c.1762A>G p.S588G | Missense Mutation (SNP) | VAF 132/430 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, varscan2
- ATG5 | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ATP9A | c.479_482dup p.I162Yfs*4 | Frame Shift Ins (INS) | VAF 160/1456 reads (11%) | called by mutect2, pindel
- BEND2 | c.431G>C p.R144T | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- BNC2 | c.2266A>C p.S756R | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BRINP3 | c.877T>A p.S293T | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BTBD11 | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CCDC60 | c.1292A>G p.K431R | Missense Mutation (SNP) | VAF 20/650 reads (3%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.844); called by muse, mutect2
- CCNG2 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CDCP2 | c.791T>C p.M264T | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CDKL5 | c.1427C>G p.S476C | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP112 | c.1668G>T p.L556F | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CFI | c.1694A>T p.Y565F | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD4 | c.3509G>A p.R1170H (on ENST00000357008 / NM_001363606.2; = p.R1183H on NM_001273.5) | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHM | c.619A>T p.T207S | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by mutect2, varscan2
- CKMT2 | c.201C>A p.C67* | Nonsense Mutation (SNP) | VAF 33/141 reads (23%) | called by muse, mutect2, varscan2
- CLEC4G | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A2 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- CPA5 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD3 | c.5892T>A p.N1964K (on ENST00000297405 / NM_001363185.1; = p.N1860K on NM_052900.3) | Missense Mutation (SNP) | VAF 74/456 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CSMD3 | c.5891A>G p.N1964S (on ENST00000297405 / NM_001363185.1; = p.N1860S on NM_052900.3) | Missense Mutation (SNP) | VAF 73/453 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CUL3 | c.1842+1_1842+2insC p.X614_splice | Splice Site (INS) | VAF 13/92 reads (14%) | called by mutect2, pindel, varscan2
- DEFA4 | c.33_49del p.L12Pfs*10 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel
- DNHD1 | c.13069C>T p.P4357S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- E2F7 | c.1920G>T p.K640N | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- EHMT1 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.691); called by muse, mutect2
- ESCO2 | c.915G>T p.E305D | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAM47A | c.791T>A p.L264Q | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- FAT1 | c.2548G>T p.D850Y | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM2 | c.7081G>T p.E2361* | Nonsense Mutation (SNP) | VAF 45/242 reads (19%) | called by muse, mutect2, varscan2
- FYB1 | c.1991C>T p.A664V (on ENST00000351578 / NM_199335.5; = p.A710V on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GABRR2 | c.155_156delinsT p.K52Mfs*17 | Frame Shift Del (DEL) | VAF 62/407 reads (15%) | called by pindel, varscan2*
- GALNT8 | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR119 | c.702T>A p.F234L | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- GRM3 | c.1202C>A p.A401D | Missense Mutation (SNP) | VAF 48/519 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- H4C2 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HFM1 | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.836); called by mutect2, varscan2
- HMOX1 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HNRNPC | c.412A>T p.S138C (on ENST00000420743; = p.S125C on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- HSPBAP1 | c.1037C>A p.A346E | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- ITFG1 | c.1466G>A p.S489N | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGB2 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- KIAA0100 | c.4472dup p.L1491Ffs*4 | Frame Shift Ins (INS) | VAF 16/80 reads (20%) | called by mutect2, pindel, varscan2
- LRP1B | c.8411C>G p.T2804R | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- MAP1A | c.3277G>T p.A1093S | Missense Mutation (SNP) | VAF 49/371 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPT | c.1043C>A p.S348Y (on ENST00000262410 / NM_001377265.1; = p.S273Y on NM_016835.4) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- MAS1 | c.755_756del p.Y252* | Frame Shift Del (DEL) | VAF 31/190 reads (16%) | called by mutect2, pindel, varscan2
- MCAM | c.1798C>A p.L600I | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MLLT10 | c.2942A>T p.Q981L (on ENST00000307729 / NM_001195626.3; = p.Q997L on NM_004641.3) | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MPEG1 | c.1798C>A p.P600T | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- NEXMIF | c.1265A>T p.K422M | Missense Mutation (SNP) | VAF 244/906 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NGLY1 | c.1602C>A p.D534E | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OMG | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 25/867 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.696); called by muse, mutect2
- OR10H5 | c.6G>T p.Q2H | Missense Mutation (SNP) | VAF 78/366 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by muse, mutect2
- OR10T2 | c.551C>G p.P184R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2B2 | c.486G>T p.W162C | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- OR5M1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- OR9G4 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 52/337 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PAPPA2 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 117/515 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.266); called by muse, mutect2
- PEX2 | c.872A>T p.Q291L | Missense Mutation (SNP) | VAF 85/581 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PIGW | c.1034T>A p.L345Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PPP4R1 | c.1861_1888del p.L621Tfs*25 (on ENST00000400556 / NM_001042388.3; = p.L604Tfs*25 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 46/191 reads (24%) | called by mutect2, pindel
- PTH2R | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 65/300 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PTPRU | c.2671G>T p.G891C | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RAPH1 | c.1145_1147del p.E382del (on ENST00000319170 / NM_213589.3; = p.E434del on NM_203365.4) | In Frame Del (DEL) | VAF 30/168 reads (18%) | called by pindel, varscan2
- RMND5A | c.194G>C p.C65S | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2
- RO60 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- RXFP1 | c.1882A>G p.K628E | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RYR2 | c.14225A>G p.H4742R | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC20A1 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC20A1 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC23A2 | c.1787A>G p.D596G | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC44A3 | c.218G>C p.G73A (on ENST00000271227 / NM_001114106.3; = p.G25A on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC5A8 | c.1165A>T p.S389C | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SLCO1C1 | c.2049G>T p.M683I | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLCO1C1 | c.2050G>T p.V684L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLITRK5 | c.2681A>C p.D894A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); called by muse, varscan2
- SPAG7 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SRPRA | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- STAB2 | c.2493del p.Y833Tfs*42 | Frame Shift Del (DEL) | VAF 29/320 reads (9%) | called by mutect2, pindel
- STK17A | c.883G>T p.V295F | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); called by muse, mutect2
- SYNE2 | c.8048A>G p.K2683R | Missense Mutation (SNP) | VAF 111/228 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TBX18 | c.1388G>A p.S463N | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- TBX3 | c.63_77del p.P22_P26del | In Frame Del (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- TDRD5 | c.1387A>T p.R463* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- TGS1 | c.764G>C p.W255S | Missense Mutation (SNP) | VAF 43/286 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR10 | c.620T>C p.L207S | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TMC1 | c.2029A>G p.I677V | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TRPV4 | c.1405del p.V469Sfs*66 | Frame Shift Del (DEL) | VAF 26/173 reads (15%) | called by mutect2, varscan2
- TTN | c.71423T>A p.V23808D (on ENST00000591111; = p.V16384D on NM_003319.4) | Missense Mutation (SNP) | VAF 41/233 reads (18%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE3A | c.2304A>T p.Q768H | Missense Mutation (SNP) | VAF 84/215 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- VPS41 | c.23A>C p.E8A | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 57/257 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- WBP2NL | c.357T>A p.N119K | Missense Mutation (SNP) | VAF 54/457 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- XRN1 | c.2163C>G p.H721Q | Missense Mutation (SNP) | VAF 101/486 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- XRN2 | c.237dup p.A80Cfs*4 | Frame Shift Ins (INS) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- YLPM1 | c.2542C>A p.H848N | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF236 | c.5172del p.C1724Wfs*46 | Frame Shift Del (DEL) | VAF 59/192 reads (31%) | called by mutect2, pindel, varscan2
- ZNF804A | c.2728G>C p.V910L | Missense Mutation (SNP) | VAF 68/359 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ATP13A1 | c.3064C>T p.L1022= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1161307104; called by muse, mutect2, varscan2
- BAZ1B | c.3867G>T p.R1289= | Silent (SNP) | VAF 34/206 reads (17%) | called by muse, mutect2, varscan2
- BPIFB3 | c.450C>T p.A150= | Silent (SNP) | VAF 62/199 reads (31%) | catalogued as rs768897443; called by muse, mutect2, varscan2
- CAND1 | c.318A>T p.S106= | Silent (SNP) | VAF 44/319 reads (14%) | called by muse, mutect2, varscan2
- CBLN2 | c.447G>A p.V149= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- CD22 | c.1356C>A p.T452= | Silent (SNP) | VAF 40/145 reads (28%) | called by muse, mutect2, varscan2
- CEP83 | c.489A>G p.E163= | Silent (SNP) | VAF 35/165 reads (21%) | called by muse, mutect2, varscan2
- CHD4 | c.3510C>T p.R1170= (on ENST00000357008 / NM_001363606.2; = p.R1183= on NM_001273.5) | Silent (SNP) | VAF 53/268 reads (20%) | catalogued as rs144001531; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD1 | c.4032C>A p.I1344= (on ENST00000520002; = p.I1343= on NM_033225.6) | Silent (SNP) | VAF 64/384 reads (17%) | catalogued as COSV59287481; called by muse, mutect2, varscan2
- ECT2L | c.1254G>A p.T418= | Silent (SNP) | VAF 36/204 reads (18%) | catalogued as rs750706600, COSV62885596; called by muse, varscan2
- FRMPD3 | c.2448A>T p.S816= | Silent (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- HDAC4 | c.741A>G p.E247= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs1040493637; called by muse, varscan2
- HLA-A | c.705G>A p.A235= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs41562919, CS099020; called by muse, varscan2
- IFIH1 | c.2496G>T p.L832= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV99718744; called by muse, mutect2, varscan2
- KCNG4 | c.426C>T p.S142= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV57585366; called by muse, mutect2, varscan2
- KCNJ11 | c.267C>A p.A89= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2
- KIAA1109 | c.7218G>A p.L2406= | Silent (SNP) | VAF 14/193 reads (7%) | called by muse, mutect2
- NHSL2 | c.2103T>C p.S701= (on ENST00000510661; = p.S1067= on NM_001013627.2) | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- NXPH4 | c.495A>G p.G165= | Silent (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- OR1L8 | c.33C>T p.S11= | Silent (SNP) | VAF 42/168 reads (25%) | catalogued as rs41305505, COSV59186044; called by muse, mutect2
- OR2A25 | c.486G>C p.L162= | Silent (SNP) | VAF 79/458 reads (17%) | called by muse, mutect2, varscan2
- PC | c.370C>A p.R124= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as CM134801, COSV63082362; called by mutect2, varscan2
- PIGZ | c.156G>A p.P52= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs202148620; called by muse, mutect2, varscan2
- PLXNA4 | c.2622C>G p.T874= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV58110601; called by muse, mutect2, varscan2
- PREX2 | c.4482C>A p.R1494= | Silent (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- PRSS35 | c.783G>A p.K261= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV63801395; called by muse, mutect2, varscan2
- RBP3 | c.2757C>A p.P919= | Silent (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- SEC23B | c.1506C>T p.A502= | Silent (SNP) | VAF 78/347 reads (22%) | called by muse, mutect2, varscan2
- SLC5A8 | c.1488A>G p.P496= | Silent (SNP) | VAF 37/215 reads (17%) | catalogued as rs774290180; called by muse, mutect2, varscan2
- SORCS1 | c.1593C>A p.V531= | Silent (SNP) | VAF 14/84 reads (17%) | called by muse, varscan2
- TARS3 | c.1353G>T p.V451= | Silent (SNP) | VAF 48/279 reads (17%) | called by muse, mutect2, varscan2
- TAS2R40 | c.819T>C p.T273= | Silent (SNP) | VAF 96/497 reads (19%) | called by muse, mutect2, varscan2
- TECTA | c.3357G>A p.Q1119= | Silent (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- TREML1 | c.15G>T p.L5= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs375030133; called by muse, mutect2, varscan2
- TRPV4 | c.1404C>T p.A468= | Silent (SNP) | VAF 26/169 reads (15%) | catalogued as rs138301077; ClinVar: likely benign; called by mutect2, varscan2
- VWF | c.4011G>A p.P1337= | Silent (SNP) | VAF 40/177 reads (23%) | catalogued as rs1800381; called by muse, mutect2, varscan2
- ZNF438 | c.525A>G p.P175= | Silent (SNP) | VAF 62/403 reads (15%) | catalogued as rs760245183, COSV59194403; called by muse, mutect2, varscan2
- PDE4D | c.456-59430G>T | Intron (SNP) | VAF 40/143 reads (28%) | called by muse, mutect2, varscan2
- TPH2 | c.609-10873C>A | Intron (SNP) | VAF 36/260 reads (14%) | catalogued as COSV100421823, COSV100422231; called by muse, mutect2, varscan2
- TTN | c.34265-3036C>T | Intron (SNP) | VAF 21/263 reads (8%) | called by muse, mutect2
- TTN | c.34265-3037C>A | Intron (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- VKORC1 | chr16:31095635 G>T | 5'Flank (SNP) | VAF 24/118 reads (20%) | called by muse, mutect2, varscan2
